Somatic mutation profile of tumor specimen TCGA-VS-A8QA-01A (aliquot TCGA-VS-A8QA-01A-11D-A37N-09) from TCGA case TCGA-VS-A8QA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: GX; Age at diagnosis: 44.0 years (16,072 days).
Specimen TCGA-VS-A8QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47f0d48e-9a77-4f90-8c41-b655712cc632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8QA-10A (Blood Derived Normal), aliquot TCGA-VS-A8QA-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc0811c2-df63-4127-a025-e06547ec0ef8

The open-access MAF lists 201 somatic variants for this specimen: 145 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 49, Nonsense Mutation 8, Intron 3, Splice Region 2, 5'Flank 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 66/231 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs371480297, COSV99228154; called by muse, mutect2, varscan2
- ACSF2 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99366060; called by muse, mutect2, varscan2
- ADAMTS7 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1415163845, COSV66306987; called by muse, mutect2, varscan2
- ADPRS | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs148612837, COSV52881894; called by muse, mutect2, varscan2
- AIFM3 | c.1152T>A p.F384L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.105); catalogued as COSV100104297; called by muse, mutect2, varscan2
- ANKRD50 | c.3983G>A p.C1328Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101538889; called by muse, mutect2, varscan2
- ANO2 | c.353C>T p.S118L (on ENST00000356134 / NM_001278597.3; = p.S122L on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs762636826, COSV59032705; called by muse, mutect2, varscan2
- ANXA4 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101268774; called by muse, mutect2, varscan2
- AP2M1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs1041547140, COSV53048327; called by muse, mutect2, varscan2
- APBA2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs575379564, COSV101381956; called by muse, mutect2, varscan2
- ARHGAP19 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100363025; called by muse, mutect2
- ASCL1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1445401828, COSV57152501; called by muse, mutect2
- ASPM | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99659643, COSV99659731; called by muse, mutect2, varscan2
- ATIC | c.1608C>G p.I536M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99377516; called by muse, mutect2, varscan2
- ATP11B | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs1395563467, COSV100017536, COSV100018092; called by muse, mutect2, varscan2
- ATP13A1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs780916050, COSV99365690; called by muse, varscan2
- BMF | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs778283404, COSV99590372; called by muse, mutect2, varscan2
- BRD8 | c.1291C>T p.P431S (on ENST00000254900 / NM_139199.2; = p.P504S on NM_006696.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as COSV50145691; called by muse, mutect2
- BTN2A1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100438395; called by muse, mutect2, varscan2
- CCDC74A | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1351387607, COSV99723587; called by muse, mutect2, varscan2
- CCDC74B | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100134206, COSV60103777; called by muse, mutect2
- CCNB3 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV99328562; called by muse, mutect2, varscan2
- CDKL1 | c.1027_1029del p.K343del | In Frame Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs750008699; called by pindel, varscan2
- CFAP47 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); catalogued as COSV99934473; called by muse, mutect2
- CFTR | c.4162C>G p.L1388V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs1554397584, COSV99134310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA10 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs780768418, COSV51703430; called by muse, mutect2, varscan2
- COL14A1 | c.2205G>C p.Q735H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99918201; called by muse, varscan2
- COL18A1 | c.2453G>A p.R818K (on ENST00000359759 / NM_130444.3; = p.R583K on NM_030582.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100700486; called by muse, mutect2
- CRTC1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58717927; called by muse, mutect2, varscan2
- CTC1 | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236179; called by muse, mutect2, varscan2
- CUL1 | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV100296459, COSV57389848; called by muse, mutect2, varscan2
- DGCR8 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100707824; called by muse, mutect2, varscan2
- DHX15 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs575114458, COSV100391175; called by muse, mutect2, varscan2
- DMXL1 | c.2431G>C p.G811R | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100223403; called by muse, mutect2, varscan2
- DNAH8 | c.11801-1G>A p.X3934_splice | Splice Site (SNP) | VAF 23/41 reads (56%) | catalogued as COSV59436524; called by muse, mutect2, varscan2
- DNAH9 | c.6964C>A p.L2322I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99304414; called by muse, mutect2, varscan2
- DNAJA3 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99276480; called by muse, mutect2, varscan2
- DROSHA | c.2880G>C p.S960= | Splice Region (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100757496; called by muse, mutect2, varscan2
- DST | c.17068G>A p.E5690K (on ENST00000361203 / NM_001374722.1; = p.E3387K on NM_015548.5) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV99751741; called by muse, mutect2, varscan2
- ELOA2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99796038; called by muse, mutect2, varscan2
- FRMD4A | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100661297; called by muse, mutect2, varscan2
- GCG | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244876125, COSV64961066, COSV64961092; called by muse, mutect2, varscan2
- GIPC3 | c.877C>T p.R293* (on ENST00000644946; = p.G288= on NM_133261.3) | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as rs759423626, COSV59258446; called by muse, mutect2, varscan2
- GK | c.1403C>T p.A468V (on ENST00000427190 / NM_001205019.2; = p.A462V on NM_000167.6) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as rs757334363, COSV66732494; called by muse, mutect2, varscan2
- GPALPP1 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100689135, COSV62705580, COSV62706659; called by muse, mutect2, varscan2
- GPNMB | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99326293; called by muse, mutect2, varscan2
- GPRIN3 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV100310608; called by muse, varscan2
- GSE1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs778332158, COSV99496124; called by muse, mutect2, varscan2
- HBP1 | c.948G>C p.L316F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99753033; called by muse, mutect2, varscan2
- HDAC5 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV99870313; called by muse, mutect2, varscan2
- HIP1 | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100417017; called by muse, mutect2, varscan2
- HIVEP1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044774; called by muse, mutect2, varscan2
- HLCS | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.253); catalogued as rs543256742, COSV100357924; called by mutect2, varscan2
- HPS5 | c.2707G>T p.E903* (on ENST00000349215 / NM_181507.2; = p.E789* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100752241, COSV61687900; called by muse, mutect2, varscan2
- HTR1A | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV100108945, COSV60500307; called by muse, mutect2, varscan2
- IFT74 | c.1042_1043insGATTTAA p.E348Gfs*8 | Frame Shift Ins (INS) | VAF 39/99 reads (39%) | catalogued as COSV101197127; called by muse*, mutect2, varscan2*
- IL1RAP | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV50763019, COSV99299091; called by muse, mutect2, varscan2
- INO80 | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100731581, COSV100732099; called by muse, mutect2, varscan2
- JPH3 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV99412899; called by muse, mutect2, varscan2
- KCTD19 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100430688; called by muse, mutect2, varscan2
- KLF12 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs375091947; called by muse, mutect2, varscan2
- LAMB4 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99223000; called by muse, mutect2, varscan2
- LEPR | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100756326, COSV60758045; called by muse, mutect2, varscan2
- LRBA | c.6626C>T p.S2209F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100841004; called by muse, mutect2, varscan2
- LRP1B | c.6701G>T p.R2234I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101253425; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs531236503, CM125282, COSV101012178; called by muse, mutect2, varscan2
- MAGEB2 | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975580; called by muse, mutect2, varscan2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MID1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100452244, COSV58197978; called by muse, mutect2, varscan2
- MIEF1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1368577524, COSV100307563; called by muse, mutect2, varscan2
- MISP | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs373218224; called by muse, mutect2, varscan2
- MLLT10 | c.2864C>G p.S955* (on ENST00000307729 / NM_001195626.3; = p.S971* on NM_004641.3) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100307509; called by muse, mutect2, varscan2
- MMP8 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV99368215; called by muse, mutect2, varscan2
- MOGS | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs778832533, COSV99270230, COSV99270330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL16 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs370390298; called by muse, mutect2, varscan2
- MRPS18B | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs1432338297, COSV99457567; called by muse, mutect2, varscan2
- MYH8 | c.755delinsATGAA p.R252Nfs*15 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | catalogued as COSV67969446; called by pindel, varscan2*
- NCOR1 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1391053845, COSV51984854; called by muse, mutect2
- OLFML2A | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV56584668; called by muse, mutect2, varscan2
- OTOA | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as rs367708830; called by muse, mutect2, varscan2
- PANX3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99421276; called by muse, mutect2, varscan2
- PARD3 | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100631139; called by muse, mutect2, varscan2
- PASD1 | c.132T>A p.F44L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100949126; called by muse, mutect2, varscan2
- PCDH15 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100216077; called by muse, mutect2, varscan2
- PCNX3 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as COSV99053538; called by muse, mutect2, varscan2
- PDE3A | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as rs759625451, COSV100761761, COSV62974844; called by muse, mutect2, varscan2
- PDIA6 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs373388851; called by muse, mutect2, varscan2
- PDXDC1 | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100362927; called by muse, mutect2, varscan2
- PFKL | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 89/132 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100827007; called by muse, mutect2, varscan2
- PHLDB2 | c.3440G>A p.R1147Q (on ENST00000393925 / NM_001134439.2; = p.R1104Q on NM_145753.2) | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs921553958, COSV67316076; called by muse, mutect2, varscan2
- PHRF1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199587; called by muse, mutect2, varscan2
- POGLUT1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV55155934, COSV99809448; called by muse, mutect2, varscan2
- PPM1D | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as rs150055145; called by muse, mutect2, varscan2
- PRPF3 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100254401; called by muse, mutect2, varscan2
- PTRH1 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV100076720; called by muse, mutect2, varscan2
- RADIL | c.2249G>A p.W750* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101271279; called by muse, mutect2, varscan2
- RBFOX1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs373077021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIC1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.341); catalogued as COSV99316728; called by muse, mutect2, varscan2
- RIMS2 | c.3104G>A p.R1035K (on ENST00000666250 / NM_001348490.2; = p.R843K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.345); catalogued as rs1254920888, COSV99163062; called by muse, mutect2, varscan2
- RNF40 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100221919; called by muse, mutect2, varscan2
- ROS1 | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs146533107, COSV63856917; called by muse, mutect2, varscan2
- RTL5 | c.1663C>G p.P555A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV101029899; called by muse, mutect2
- RUNX1T1 | c.1357G>A p.V453I (on ENST00000265814 / NM_001198628.1; = p.V426I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs1441480264, COSV99749787, COSV99754196; called by muse, mutect2, varscan2
- SAMD9L | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100560365; called by muse, mutect2, varscan2
- SEMA3E | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.21); catalogued as COSV57110727; called by muse, mutect2, varscan2
- SEMA5B | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs777855447, COSV52103831, COSV99532509; called by muse, mutect2, varscan2
- SLC14A2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV54909266, COSV99675336; called by muse, mutect2, varscan2
- SLC24A1 | c.3182C>T p.S1061L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.127); catalogued as COSV56052889; called by muse, mutect2, varscan2
- SLC35A5 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV99656707; called by muse, mutect2, varscan2
- SLFN11 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100390370; called by muse, mutect2, varscan2
- SLIT2 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as rs755579697, COSV56573143; called by muse, mutect2, varscan2
- SLITRK5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61520512; called by muse, mutect2, varscan2
- SNRPC | c.72C>A p.H24Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765169; called by muse, mutect2, varscan2
- SON | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as rs771291043, COSV99277043; called by muse, mutect2, varscan2
- SPEG | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs938901169, COSV100403437; called by muse, mutect2, varscan2
- SRL | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs372047118; called by muse, mutect2, varscan2
- SUGP2 | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV100431526; called by muse, mutect2, varscan2
- SYDE2 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99320254; called by muse, mutect2, varscan2
- SZT2 | c.5989G>A p.E1997K (on ENST00000634258 / NM_001365999.1; = p.E1940K on NM_015284.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100986931; called by muse, mutect2, varscan2
- TEAD3 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758902471, COSV100132293; called by muse, mutect2, varscan2
- TKTL1 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.4); catalogued as COSV99473747; called by muse, mutect2, varscan2
- TLE3 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58166389; called by muse, mutect2, varscan2
- TLL1 | c.2895C>A p.F965L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1490705887, COSV50269951; called by muse, mutect2, varscan2
- TMEM245 | c.1975C>T p.L659= | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as COSV65824119; called by muse, mutect2, varscan2
- TNS3 | c.2411C>A p.P804Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100234871; called by muse, mutect2, varscan2
- TP73 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100600985; called by muse, mutect2, varscan2
- TPTE | c.761C>T p.S254F (on ENST00000618007 / NM_199261.4; = p.S236F on NM_199259.4) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs769873939; called by muse, mutect2, varscan2
- TRPM7 | c.3025C>T p.L1009F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100539440; called by muse, mutect2, varscan2
- TUBA4A | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99944629; called by muse, mutect2, varscan2
- TUFM | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs373054580; called by muse, mutect2, varscan2
- UNC13C | c.1514C>G p.S505* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99512429; called by muse, mutect2, varscan2
- VGLL4 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99809240; called by muse, mutect2, varscan2
- VPS13D | c.11218G>C p.D3740H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV99165573; called by muse, mutect2, varscan2
- WDR33 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59247825; called by muse, mutect2, varscan2
- ZNF20 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV100502858; called by muse, mutect2, varscan2
- ZNF234 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as COSV70603726; called by muse, mutect2, varscan2
- ZNF236 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV99469278; called by muse, mutect2, varscan2
- ZNF304 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV99988420; called by muse, mutect2, varscan2
- ZNF558 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100037768, COSV56864379; called by muse, mutect2, varscan2
- ZNF57 | c.1319G>C p.R440T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs201376690, COSV100182767; called by muse, mutect2, varscan2
- ZNF649 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100725358; called by muse, mutect2, varscan2
- ZNFX1 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870742; called by muse, mutect2, varscan2
- ACSF2 | c.1176C>T p.I392= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99366061; called by muse, mutect2, varscan2
- AP3D1 | c.876C>T p.S292= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs762535783, COSV100642407; called by muse, mutect2, varscan2
- ARHGEF17 | c.5772C>T p.I1924= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99734966, COSV99735015; called by muse, mutect2, varscan2
- BPIFA2 | c.749G>A p.*250= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53612468; called by muse, mutect2, varscan2
- CBY2 | c.507G>A p.Q169= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100137467; called by muse, mutect2, varscan2
- CDCA5 | c.120C>T p.I40= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99297688; called by muse, mutect2, varscan2
- CDKL5 | c.660T>G p.L220= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV101184072; called by muse, mutect2, varscan2
- CLNK | c.1095G>A p.E365= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1200575936, COSV57011703, COSV99904630; called by muse, mutect2, varscan2
- CYP4A22 | c.861G>A p.R287= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99594638; called by muse, mutect2, varscan2
- DLG1 | c.1488C>T p.A496= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs767244855, COSV58377223; called by muse, mutect2, varscan2
- DPPA2 | c.321C>T p.L107= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs772560169, COSV101524739; called by muse, mutect2, varscan2
- FANCI | c.1921C>T p.L641= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1171055536, COSV100167539; called by muse, mutect2, varscan2
- FKBP10 | c.1575C>T p.F525= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99505068; called by muse, mutect2, varscan2
- FOXR1 | c.867C>G p.L289= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100392811; called by muse, mutect2, varscan2
- FRMPD3 | c.2625C>G p.L875= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99345754, COSV99345998; called by muse, mutect2, varscan2
- FXR1 | c.537G>A p.K179= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV99976178; called by muse, mutect2
- GNRH2 | c.285G>A p.R95= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99848602; called by muse, mutect2, varscan2
- GRIN2D | c.1497C>T p.I499= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV99615961; called by muse, mutect2, varscan2
- HOXA7 | c.573C>T p.D191= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99636181; called by muse, mutect2, varscan2
- IRGC | c.432C>A p.R144= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99746088; called by muse, mutect2
- IRS4 | c.1275G>A p.A425= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs779923247, COSV100929446; called by muse, mutect2, varscan2
- KHSRP | c.1935G>A p.T645= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs956206324, COSV67920202; called by muse, mutect2, varscan2
- MSRB3 | c.132C>T p.V44= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV57600286; called by muse, mutect2, varscan2
- MYO7A | c.522C>T p.F174= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV101289055, COSV68684929; called by muse, mutect2, varscan2
- MYOM2 | c.1449C>T p.L483= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV50764964; called by muse, mutect2, varscan2
- NOTCH2 | c.3987C>T p.F1329= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs1260847069, COSV99862966; called by muse, mutect2, varscan2
- OR2B11 | c.840C>A p.L280= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100275339; called by muse, mutect2, varscan2
- PDZD2 | c.7179G>A p.L2393= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99223899; called by muse, mutect2, varscan2
- PHF20L1 | c.280C>T p.L94= | Silent (SNP) | VAF 53/75 reads (71%) | catalogued as COSV99620461; called by muse, mutect2, varscan2
- PIDD1 | c.534G>A p.V178= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100758527; called by muse, mutect2, varscan2
- PPP2R3A | c.3417G>A p.E1139= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV99386545; called by muse, mutect2, varscan2
- RBM47 | c.588C>T p.F196= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1392253835, COSV99920212; called by muse, mutect2, varscan2
- SDC4 | c.522G>A p.K174= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV101023370; called by muse, mutect2, varscan2
- SERPINE1 | c.1029G>A p.A343= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs551975867, COSV99776591; called by muse, mutect2, varscan2
- SLC16A11 | c.345C>T p.A115= (on ENST00000308009; = p.A91= on NM_153357.3) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100338566; called by muse, mutect2, varscan2
- SLC38A10 | c.531C>T p.L177= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99917208; called by muse, mutect2, varscan2
- SLC5A9 | c.618C>T p.L206= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99361389; called by muse, mutect2, varscan2
- STAB1 | c.3186C>T p.F1062= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as rs372560660; called by muse, mutect2, varscan2
- TBC1D2 | c.1662G>A p.L554= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1461295202, COSV100579725; called by muse, mutect2, varscan2
- THEMIS2 | c.1083G>A p.E361= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100197912, COSV61077350; called by muse, mutect2, varscan2
- TM4SF5 | c.42C>T p.L14= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs370279531; called by muse, mutect2, varscan2
- TSC22D3 | c.174G>A p.E58= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100226683; called by muse, mutect2, varscan2
- UPF1 | c.1026C>T p.I342= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs780792461, COSV53194604; called by muse, mutect2, varscan2
- VPS16 | c.150G>A p.L50= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100988295; called by muse, mutect2, varscan2
- XRCC1 | c.279C>T p.F93= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99486281; called by muse, mutect2, varscan2
- ZBTB22 | c.1524C>T p.L508= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99801544; called by muse, mutect2, varscan2
- ZC2HC1C | c.510G>A p.P170= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs768894302, COSV99472817; called by muse, mutect2, varscan2
- ZNF208 | c.2136G>A p.K712= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1430208815, COSV68103826; called by muse, mutect2, varscan2
- ZXDA | c.1779G>A p.Q593= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100699371; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840612 G>A | 5'Flank (SNP) | VAF 28/119 reads (24%) | catalogued as rs768082058, COSV58341425; called by muse, mutect2, varscan2
- CERS5 | c.-1G>A | 5'UTR (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100451915; called by muse, mutect2, varscan2
- KLHL4 | c.*2821C>T | 3'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as rs12013438, COSV100909200, COSV64139639; called by muse, mutect2, varscan2
- MSL3 | c.1171+14C>T | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs772470103, COSV100384587; called by muse, mutect2, varscan2
- PITX2 | c.185-992G>A | Intron (SNP) | VAF 50/116 reads (43%) | catalogued as COSV100146216, COSV100146375; called by muse, mutect2, varscan2
- PTCD3 | c.1779-617C>T | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99606059; called by muse, mutect2, varscan2
- TTI2 | chr8:33513573 C>T | 5'Flank (SNP) | VAF 11/20 reads (55%) | catalogued as rs577311432, COSV100659631; called by muse, mutect2, varscan2
